Somatic mutation profile of tumor specimen TCGA-B5-A11I-01A (aliquot TCGA-B5-A11I-01A-11D-A10M-09) from TCGA case TCGA-B5-A11I, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 65.3 years (23,857 days).
Specimen TCGA-B5-A11I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8691da77-83b8-4923-a31d-1e3217dac938.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11I-10A (Blood Derived Normal), aliquot TCGA-B5-A11I-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afc92885-bcbf-452e-8c8c-549523573aa5

The open-access MAF lists 55 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 37, Silent 11, Splice Site 3, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 38/64 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3012G>T p.M1004I | Missense Mutation (SNP) | VAF 45/74 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV55881019, COSV55891097; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 116/185 reads (63%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs147807073, CM1411991; called by muse, mutect2, varscan2
- ACSM2B | c.1262G>A p.G421D | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as rs138313327; called by muse, mutect2, varscan2
- ADGRG4 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as rs768398877, COSV54948565; called by muse, mutect2, varscan2
- ARID3B | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.058); catalogued as COSV60557983; called by muse, mutect2
- ARL16 | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.545); catalogued as COSV100230412, COSV61268347; called by muse, mutect2, varscan2
- BOD1L1 | c.2553G>C p.Q851H | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV50018625; called by muse, mutect2, varscan2
- CENPBD1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 25/508 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1440818995, COSV51919575; called by muse, mutect2
- CEP290 | c.4507A>C p.N1503H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1410895455, COSV58352729; called by muse, mutect2
- CES3 | c.1051C>A p.L351I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.173); catalogued as COSV57593964; called by muse, mutect2, varscan2
- CHD6 | c.4189C>G p.R1397G | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64691689; called by muse, mutect2, varscan2
- CLPX | c.760G>T p.G254* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | catalogued as COSV55645037; called by muse, mutect2, varscan2
- CLSTN2 | c.1970C>T p.T657I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV71721483; called by muse, mutect2, varscan2
- DHX30 | c.3343C>T p.R1115W (on ENST00000445061 / NM_138615.3; = p.R1076W on NM_014966.3) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs998585446; called by muse, mutect2
- DNAJB2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 91/309 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60676941; called by muse, mutect2, varscan2
- DYNC2I1 | c.2886G>C p.W962C | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101337683, COSV68105308; called by muse, mutect2, varscan2
- EIF4G3 | c.2482G>A p.G828S | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV51684936; called by muse, mutect2, varscan2
- FOXP4 | c.1357+1G>A p.X453_splice (on ENST00000307972 / NM_001012426.1; = p.X440_splice on NM_138457.3) | Splice Site (SNP) | VAF 52/124 reads (42%) | catalogued as COSV57220746; called by muse, mutect2, varscan2
- IARS1 | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.812); catalogued as COSV65115760; called by muse, mutect2, varscan2
- KRT32 | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56786943; called by muse, mutect2, varscan2
- KYAT3 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53102262, COSV53104010; called by muse, mutect2
- MCM4 | c.974C>G p.P325R | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50625000; called by muse, mutect2, varscan2
- NECTIN1 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748582329, COSV50601465; called by muse, mutect2, varscan2
- NID2 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768317625, COSV53497810, COSV99356317; called by muse, mutect2, varscan2
- OR5P2 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as COSV61490756, COSV61490963; called by muse, varscan2
- PLK3 | c.1635+2T>C p.X545_splice | Splice Site (SNP) | VAF 100/268 reads (37%) | catalogued as COSV59500113; called by muse, mutect2, varscan2
- PPIAL4G | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV70087154; called by mutect2, varscan2
- RIPOR3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs1271751658, COSV50391664; called by muse, varscan2
- SLC5A1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201079555, CM961328, COSV56686148; called by muse, mutect2, varscan2
- SPANXN4 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.585); catalogued as rs1420639569, COSV65141466; called by muse, mutect2, varscan2
- SULF2 | c.2495-1G>A p.X832_splice | Splice Site (SNP) | VAF 40/110 reads (36%) | catalogued as COSV59069725; called by muse, mutect2, varscan2
- TAF1 | c.1993G>A p.E665K (on ENST00000373790 / NM_138923.4; = p.E686K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52115987, COSV99337018; called by muse, mutect2, varscan2
- TBL3 | c.2163G>A p.W721* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV60341897; called by muse, mutect2, varscan2
- TMEM225 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV66693524; called by muse, mutect2
- WWC3 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs762993233, COSV66504091; called by muse, mutect2, varscan2
- XIRP2 | c.5513G>T p.R1838I (on ENST00000628543; = p.R2013I on NM_152381.6) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV54685355, COSV54692951; called by muse, mutect2
- ZC3H12A | c.729C>G p.N243K | Missense Mutation (SNP) | VAF 267/627 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66104186, COSV66104426; called by muse, mutect2, varscan2
- ZFYVE19 | c.1097G>C p.R366T (on ENST00000355341 / NM_001077268.2; = p.R356T on NM_032850.5) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV54540687; called by muse, mutect2, varscan2
- ZNF25 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56922890; called by muse, mutect2, varscan2
- ZNF611 | c.658C>G p.Q220E | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV60541465; called by muse, mutect2, varscan2
- GTF2I | c.2560G>A p.D854N (on ENST00000573035 / NM_032999.4; = p.D813N on NM_001518.5) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PLCE1 | c.6178_6205del p.F2060Lfs*26 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel
- ACSM2B | c.1263C>A p.G421= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV61658310; called by muse, mutect2, varscan2
- ASPHD1 | c.555G>A p.Q185= | Silent (SNP) | VAF 75/193 reads (39%) | catalogued as COSV58100387; called by muse, mutect2, varscan2
- HTR1F | c.276G>A p.G92= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV60390006; called by muse, mutect2, varscan2
- MS4A7 | c.159C>A p.I53= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV55730147; called by muse, mutect2
- NEO1 | c.1683A>T p.T561= | Silent (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- OR4X1 | c.588G>T p.L196= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV60723132; called by muse, mutect2, varscan2
- PCK1 | c.1830A>G p.R610= | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- PTPRJ | c.1653C>A p.V551= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV101395406, COSV69252758; called by muse, mutect2, varscan2
- SCUBE2 | c.246G>A p.R82= | Silent (SNP) | VAF 163/426 reads (38%) | catalogued as rs769564761, COSV58543575; called by muse, mutect2, varscan2
- SRCAP | c.2541G>A p.K847= | Silent (SNP) | VAF 30/299 reads (10%) | catalogued as COSV52674769; called by muse, mutect2
- XYLT2 | c.1260G>A p.V420= | Silent (SNP) | VAF 134/334 reads (40%) | catalogued as COSV50018696; called by muse, mutect2, varscan2
